Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI4, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI4-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 3.5 cm; no rete testis available; no angio-invasion; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O3

Seminoma NOS 9061/3

Site @ Testis NOS 662.9

3/2/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 736965cd-16d4-4ab3-a6eb-52ed9f8eb5d7 (TCGA-2G-AAI4-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).